Somatic mutation profile of tumor specimen ALCH-B1Y1-TTP1-A (aliquot ALCH-B1Y1-TTP1-A-1-0-D-A772-36) from ALCHEMIST case ALCH-B1Y1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.4 years (26,442 days).
Specimen ALCH-B1Y1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e55dc54-6d6a-4137-a0f0-c1bd311e6966.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1Y1-NB1-A (Blood Derived Normal), aliquot ALCH-B1Y1-NB1-A-1-0-D-A772-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46372773-7a04-422b-971e-bede64078030

The open-access MAF lists 172 somatic variants for this specimen: 123 protein-altering or splice-affecting, 34 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 34, Intron 8, Nonsense Mutation 8, RNA 4, Splice Site 3, 3'Flank 1, 3'UTR 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 32/672 reads (5%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ANKRD42 | c.247-1G>T p.X83_splice | Splice Site (SNP) | VAF 18/428 reads (4%) | catalogued as rs1313272579, COSV99473698; called by muse, mutect2
- ASTN1 | c.2019C>A p.D673E | Missense Mutation (SNP) | VAF 26/598 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV56062762; called by muse, mutect2
- BRINP3 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 34/538 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100818417, COSV100819618; called by muse, mutect2
- CATSPER2 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 30/658 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs537438961; called by muse, mutect2
- CDKL3 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0.257); catalogued as rs1214181005; called by muse, mutect2
- CFAP46 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1158805265; called by muse, mutect2
- COL5A2 | c.3703G>A p.D1235N | Missense Mutation (SNP) | VAF 26/614 reads (4%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.666); catalogued as rs1185247065, COSV66409780; called by muse, mutect2
- CTNNA2 | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 22/509 reads (4%) | catalogued as rs1215410582, COSV63589936, COSV63602878; called by muse, mutect2
- DISP1 | c.3769G>A p.E1257K | Missense Mutation (SNP) | VAF 16/554 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.024); catalogued as COSV52662779; called by muse, mutect2
- EIF2AK4 | c.2667G>C p.L889F | Missense Mutation (SNP) | VAF 16/239 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs1173123532; called by muse, mutect2
- FAM181A | c.802G>T p.G268C | Missense Mutation (SNP) | VAF 25/555 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV99967906; called by muse, mutect2
- FFAR1 | c.376G>C p.V126L | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.558); catalogued as rs141553335, COSV50051598, COSV99323731; called by muse, mutect2
- FLOT2 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs1218706690, COSV67529513; called by muse, mutect2
- FLT4 | c.2083C>A p.L695M | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.481); catalogued as COSV56101106; called by muse, mutect2
- HDAC6 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.705); catalogued as COSV61930542; called by muse, mutect2
- IL1RL2 | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 28/829 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.107); catalogued as COSV51817654; called by muse, mutect2
- MED13 | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV67266548; called by muse, mutect2
- NAXD | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as rs1187397737, COSV57286743; called by muse, mutect2
- NBAS | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 35/698 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs565228279, COSV104386095, COSV99871290; called by muse, mutect2
- OR1L1 | c.724C>A p.H242N (on ENST00000373686; = p.H192N on NM_001005236.3) | Missense Mutation (SNP) | VAF 15/294 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV58936034; called by muse, mutect2
- OR2T35 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 54/1192 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1236670402; called by muse, mutect2
- OR52J3 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 17/380 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs1436910395, COSV100984840; called by muse, mutect2
- PCDHB11 | c.1090G>T p.V364L | Missense Mutation (SNP) | VAF 22/464 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.515); catalogued as COSV61310690; called by muse, mutect2
- PDE11A | c.2794A>G p.R932G | Missense Mutation (SNP) | VAF 38/731 reads (5%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs1273323715; called by muse, mutect2
- PDE6C | c.1646T>A p.M549K | Missense Mutation (SNP) | VAF 38/952 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as rs755503558, COSV65116577; called by muse, mutect2
- PGAP2 | c.536C>T p.S179F (on ENST00000463452 / NM_001346398.2; = p.S240F on NM_014489.4) | Missense Mutation (SNP) | VAF 26/325 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99544577; called by muse, mutect2
- PUS1 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 32/514 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1242866089; called by muse, mutect2
- SEMA4C | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.021); catalogued as rs1383016653; called by muse, mutect2
- SLC6A1 | c.693G>T p.K231N | Missense Mutation (SNP) | VAF 13/357 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55117685; called by muse, mutect2
- STARD9 | c.13333C>T p.R4445* | Nonsense Mutation (SNP) | VAF 14/400 reads (4%) | catalogued as rs974184012; called by muse, mutect2
- TOPAZ1 | c.290C>A p.P97Q | Missense Mutation (SNP) | VAF 20/482 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV59064056; called by muse, mutect2
- TRIM11 | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 45/449 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.347); catalogued as COSV99488841; called by muse, mutect2, varscan2
- USP8 | c.1092G>C p.L364F | Missense Mutation (SNP) | VAF 21/594 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1301593548, COSV56162903; called by muse, mutect2
- VCAN | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 30/972 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs977327386, COSV54103469; called by muse, mutect2
- ZNF135 | c.1504G>A p.A502T (on ENST00000313434 / NM_001289401.2; = p.A514T on NM_003436.4) | Missense Mutation (SNP) | VAF 64/697 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.627); catalogued as rs1395286497; called by muse, mutect2
- ZNF646 | c.785C>T p.T262M | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs373729885; called by muse, mutect2
- ZNF653 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 15/388 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV53402334, COSV99542308; called by muse, mutect2
- AC069544.2 | c.360C>G p.H120Q | Missense Mutation (SNP) | VAF 19/337 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- ACSS2 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 11/259 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- ACSS2 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 11/253 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2
- ADAM19 | c.1811A>G p.Q604R | Missense Mutation (SNP) | VAF 30/710 reads (4%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2
- ADAMTS8 | c.2293A>T p.K765* | Nonsense Mutation (SNP) | VAF 16/252 reads (6%) | called by muse, mutect2
- ADGRL3 | c.349G>T p.D117Y (on ENST00000506720 / NM_001322402.2; = p.D49Y on NM_015236.6) | Missense Mutation (SNP) | VAF 29/518 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGAP27 | c.1686G>T p.R562S (on ENST00000428638 / NM_001282290.1; = p.R221S on NM_199282.3) | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.318); called by muse, mutect2
- ARHGAP29 | c.3489G>T p.W1163C | Missense Mutation (SNP) | VAF 25/967 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); called by muse, mutect2
- ASPM | c.6650A>T p.K2217I | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.242); called by muse, mutect2
- ATN1 | c.3503A>T p.H1168L | Missense Mutation (SNP) | VAF 34/616 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- ATXN2L | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 13/286 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- B4GALT6 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 42/575 reads (7%) | called by muse, mutect2
- BSN | c.7498C>A p.Q2500K | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2
- CHL1 | c.1988C>T p.T663I (on ENST00000397491 / NM_001253387.1; = p.T679I on NM_006614.4) | Missense Mutation (SNP) | VAF 31/664 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, mutect2
- CHRNB1 | c.1333C>G p.R445G | Missense Mutation (SNP) | VAF 36/580 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.376); called by muse, mutect2
- CLEC9A | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 12/354 reads (3%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); called by muse, mutect2
- COL22A1 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2
- COLQ | c.659A>T p.E220V | Missense Mutation (SNP) | VAF 32/882 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2
- CSMD1 | c.10234C>A p.L3412I (on ENST00000520002; = p.L3411I on NM_033225.6) | Missense Mutation (SNP) | VAF 14/424 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- CSMD1 | c.7061T>C p.V2354A (on ENST00000520002; = p.V2353A on NM_033225.6) | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); called by muse, mutect2
- DGKI | c.694T>C p.C232R | Missense Mutation (SNP) | VAF 51/513 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DIXDC1 | c.711G>T p.Q237H (on ENST00000440460 / NM_001037954.4; = p.Q26H on NM_033425.4) | Missense Mutation (SNP) | VAF 17/460 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.227); called by muse, mutect2
- DNAH5 | c.6833C>T p.A2278V | Missense Mutation (SNP) | VAF 18/538 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2
- ERCC6 | c.3117G>C p.R1039S | Missense Mutation (SNP) | VAF 12/263 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- ERI2 | c.1993C>G p.P665A | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2
- ERICH3 | c.4021G>T p.E1341* | Nonsense Mutation (SNP) | VAF 32/712 reads (4%) | called by muse, mutect2
- FADD | c.320A>T p.N107I | Missense Mutation (SNP) | VAF 37/552 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- FAM151A | c.1160C>A p.T387N | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.153); called by muse, mutect2
- FAM241A | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 18/536 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- FCGR3A | c.105C>A p.Y35* | Nonsense Mutation (SNP) | VAF 90/1104 reads (8%) | called by muse, mutect2
- GABRA1 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 42/930 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2
- GDF2 | c.593A>T p.Q198L | Missense Mutation (SNP) | VAF 14/341 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.023); called by muse, mutect2
- GPR161 | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.378); called by muse, mutect2
- HDAC9 | c.2675+1G>C p.X892_splice | Splice Site (SNP) | VAF 13/256 reads (5%) | called by muse, mutect2
- HSPG2 | c.7639A>G p.N2547D | Missense Mutation (SNP) | VAF 17/382 reads (4%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.815); called by muse, mutect2
- ICAM2 | c.588G>C p.L196F | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGKV2D-26 | c.200C>A p.P67Q | Missense Mutation (SNP) | VAF 30/1089 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- JAK2 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.143); called by muse, mutect2
- KCNJ5 | c.377G>C p.W126S | Missense Mutation (SNP) | VAF 48/975 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- LAMA2 | c.3964A>G p.R1322G | Missense Mutation (SNP) | VAF 26/816 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- LMNTD1 | c.779A>G p.E260G | Missense Mutation (SNP) | VAF 24/514 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2
- LRRC7 | c.2627C>A p.P876H (on ENST00000651989 / NM_001370785.2; = p.P843H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/410 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.477); called by muse, mutect2
- MAGEB16 | c.902A>T p.Y301F | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MARCHF4 | c.100C>G p.H34D | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.038); called by muse, mutect2
- MAX | c.64-1G>T p.X22_splice | Splice Site (SNP) | VAF 39/960 reads (4%) | called by muse, mutect2
- MPHOSPH8 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 38/956 reads (4%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); called by muse, mutect2
- MROH5 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- MUC5B | c.5110G>A p.G1704R | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MYCBPAP | c.1994T>A p.L665H | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- MYLK | c.3947T>A p.L1316Q | Missense Mutation (SNP) | VAF 32/644 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2
- MYRIP | c.674T>G p.L225R | Missense Mutation (SNP) | VAF 24/592 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NLRP8 | c.1132C>A p.Q378K | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- NSD3 | c.1809+5G>T | Splice Region (SNP) | VAF 33/501 reads (7%) | called by muse, mutect2
- OR10W1 | c.712G>T p.V238L | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- OR2T1 | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 14/295 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR5H2 | c.909A>G p.I303M | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.06); called by muse, mutect2
- PAPSS2 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 29/782 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDZD9 | c.151C>A p.L51I | Missense Mutation (SNP) | VAF 17/311 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PPP1R9A | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 24/618 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.162); called by muse, mutect2
- PREX1 | c.4063G>T p.E1355* | Nonsense Mutation (SNP) | VAF 15/388 reads (4%) | called by muse, mutect2
- PZP | c.4148A>T p.N1383I | Missense Mutation (SNP) | VAF 20/598 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RAD23B | c.736A>T p.S246C | Missense Mutation (SNP) | VAF 16/321 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); called by muse, mutect2
- RNF123 | c.439A>G p.M147V | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- RP1L1 | c.2834C>A p.P945H | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- RTL1 | c.3457G>T p.V1153L | Missense Mutation (SNP) | VAF 19/344 reads (6%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2
- SAMD5 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 27/600 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCN5A | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.132); called by muse, mutect2
- SCRIB | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 30/468 reads (6%) | called by muse, mutect2
- SETBP1 | c.2351G>T p.G784V | Missense Mutation (SNP) | VAF 104/1174 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- SGIP1 | c.1112T>C p.L371P | Missense Mutation (SNP) | VAF 32/548 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- SH2B1 | c.979A>T p.T327S | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); called by muse, mutect2
- SHANK3 | c.2384C>G p.S795W | Missense Mutation (SNP) | VAF 11/294 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- SLC14A1 | c.289T>A p.W97R | Missense Mutation (SNP) | VAF 78/830 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2
- SLC8A3 | c.930T>A p.D310E | Missense Mutation (SNP) | VAF 28/598 reads (5%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.855); called by muse, mutect2
- SLC9A3 | c.1025T>A p.L342Q | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- SNRNP200 | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 39/990 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- SORCS3 | c.2968G>T p.D990Y | Missense Mutation (SNP) | VAF 15/330 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- TEX15 | c.6253A>C p.K2085Q (on ENST00000256246; = p.K2468Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2
- TEX30 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 20/480 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.111); called by muse, mutect2
- TLL1 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 29/694 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- TMEM9B | c.287G>C p.R96T | Missense Mutation (SNP) | VAF 18/395 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TP53I11 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- USP42 | c.151A>G p.T51A | Missense Mutation (SNP) | VAF 28/658 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2
- ZNF250 | c.1570C>G p.Q524E | Missense Mutation (SNP) | VAF 20/528 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.247); called by muse, mutect2
- ZNF714 | c.426G>C p.E142D | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.295); called by muse, mutect2
- ACAP1 | c.552G>A p.R184= | Silent (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- ADAMTS8 | c.2292G>A p.L764= | Silent (SNP) | VAF 18/262 reads (7%) | catalogued as COSV57291018; called by muse, mutect2
- ATP13A4 | c.102C>G p.L34= | Silent (SNP) | VAF 30/761 reads (4%) | called by muse, mutect2
- CATIP | c.246G>A p.L82= | Silent (SNP) | VAF 32/688 reads (5%) | called by muse, mutect2
- CCDC61 | c.513G>T p.R171= | Silent (SNP) | VAF 28/314 reads (9%) | called by muse, mutect2
- CDAN1 | c.1761C>T p.L587= | Silent (SNP) | VAF 44/872 reads (5%) | catalogued as rs775597322; called by muse, mutect2
- COMTD1 | c.300C>A p.L100= | Silent (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- EGF | c.3623G>A p.*1208= | Silent (SNP) | VAF 22/584 reads (4%) | catalogued as COSV99491345, COSV99491491; called by muse, mutect2
- ERICH3 | c.2763C>T p.A921= | Silent (SNP) | VAF 28/472 reads (6%) | called by muse, mutect2
- FPR1 | c.951C>T p.P317= | Silent (SNP) | VAF 56/792 reads (7%) | catalogued as rs570072877, COSV59051130; called by muse, mutect2
- GON4L | c.6651T>C p.D2217= | Silent (SNP) | VAF 38/900 reads (4%) | called by muse, mutect2
- HCN2 | c.948C>T p.V316= | Silent (SNP) | VAF 18/377 reads (5%) | called by muse, mutect2
- IL1RL2 | c.162A>T p.V54= | Silent (SNP) | VAF 25/808 reads (3%) | called by muse, mutect2
- MAGEC2 | c.129T>A p.S43= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- MET | c.3327G>A p.V1109= | Silent (SNP) | VAF 62/912 reads (7%) | called by muse, mutect2
- MFAP4 | c.171C>T p.I57= | Silent (SNP) | VAF 12/211 reads (6%) | called by muse, mutect2
- MUC16 | c.2118C>A p.P706= | Silent (SNP) | VAF 29/569 reads (5%) | called by muse, mutect2
- MYH4 | c.4701T>C p.L1567= | Silent (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- NCOA1 | c.81G>A p.L27= | Silent (SNP) | VAF 28/576 reads (5%) | called by muse, mutect2
- NOS2 | c.519A>T p.I173= | Silent (SNP) | VAF 20/467 reads (4%) | called by muse, mutect2
- NPC1L1 | c.2568G>A p.L856= | Silent (SNP) | VAF 24/646 reads (4%) | called by muse, mutect2
- NUF2 | c.375C>T p.I125= | Silent (SNP) | VAF 29/808 reads (4%) | called by muse, mutect2
- OR2G2 | c.723C>T p.F241= | Silent (SNP) | VAF 26/395 reads (7%) | catalogued as rs765219287, COSV60740172; called by muse, mutect2
- OR4D11 | c.381C>A p.S127= | Silent (SNP) | VAF 10/242 reads (4%) | called by muse, mutect2
- OR8G1 | c.114A>G p.T38= | Silent (SNP) | VAF 32/556 reads (6%) | called by muse, mutect2
- OTOP2 | c.444C>T p.I148= | Silent (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- PCDHB16 | c.2247C>T p.Y749= | Silent (SNP) | VAF 17/588 reads (3%) | called by muse, mutect2
- RECQL4 | c.954G>A p.R318= | Silent (SNP) | VAF 31/323 reads (10%) | called by muse, mutect2
- SEMA4C | c.30G>T p.L10= | Silent (SNP) | VAF 24/414 reads (6%) | called by muse, mutect2
- SLC23A3 | c.189C>T p.L63= | Silent (SNP) | VAF 17/307 reads (6%) | called by muse, mutect2
- SLC25A46 | c.57G>T p.R19= | Silent (SNP) | VAF 32/642 reads (5%) | called by muse, mutect2
- TBX5 | c.255C>A p.P85= | Silent (SNP) | VAF 24/581 reads (4%) | called by muse, mutect2
- TMEM63B | c.1758G>T p.L586= | Silent (SNP) | VAF 13/362 reads (4%) | called by muse, mutect2
- TMPRSS15 | c.633A>T p.P211= | Silent (SNP) | VAF 26/411 reads (6%) | called by muse, mutect2
- ABCC8 | c.3989-27G>T | Intron (SNP) | VAF 15/241 reads (6%) | called by muse, mutect2
- AC020637.1 | n.777C>A | RNA (SNP) | VAF 17/426 reads (4%) | called by muse, mutect2
- ADGRL2 | c.3270+22G>T | Intron (SNP) | VAF 13/300 reads (4%) | called by muse, mutect2
- C12orf73 | c.108+891G>C | Intron (SNP) | VAF 15/566 reads (3%) | called by muse, mutect2
- CCNB1IP1 | c.-37-3760G>T | Intron (SNP) | VAF 16/441 reads (4%) | catalogued as rs1189662836; called by muse, mutect2
- DPP9 | c.2244+315G>T | Intron (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- KIAA0895L | c.848-117T>G | Intron (SNP) | VAF 15/184 reads (8%) | called by muse, mutect2
- MATR3 | c.*758A>T | 3'UTR (SNP) | VAF 22/375 reads (6%) | called by muse, mutect2
- MSL3P1 | n.581T>A | RNA (SNP) | VAF 30/624 reads (5%) | called by muse, mutect2
- OR1D4 | n.356C>T | RNA (SNP) | VAF 40/1111 reads (4%) | catalogued as rs550070722; called by muse, mutect2
- PAX3 | chr2:222201413 C>A | 3'Flank (SNP) | VAF 52/1039 reads (5%) | catalogued as COSV60590085; called by muse, mutect2
- RPL23AP42 | n.395G>T | RNA (SNP) | VAF 50/1136 reads (4%) | called by muse, mutect2
- STARD9 | c.12765-20C>G | Intron (SNP) | VAF 21/414 reads (5%) | called by muse, mutect2
- TLE3 | c.-172G>C | 5'UTR (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- TMEM51 | c.-267+10465C>T | Intron (SNP) | VAF 55/1172 reads (5%) | called by muse, mutect2
